Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4344, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4344-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Original Rep

Date of Amendment

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Female with right renal mass; s/p right partial nephrectomy.

Specimens Submitted:

1: Tumor, kidney, right upper pole; partial nephrectomy

AMENDED DIAGNOSIS:

1. Tumor, kidney, right upper pole; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.8 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

DIAGNOSIS:

1. Local Invasion (for renal cortical types):
Extends through renal capsule but confined within Gerota's fascia

AMENDED REPORT:

DIAGNOSIS:

1. Local Invasion (for renal cortical types):
Not Identified

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section, labeled "tumor right upper pole of kidney". It consists of a 4.2 x 2.0 x 2.7 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 2.8 x 1.5 x 2.8 cm yellow hemorrhagic tumor. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Tumor is entirely submitted. Portions of the tumor are submitted for [REDACTED]

Summary of sections:

FSC - frozen section control
T - tumor

Summary of Sections:

Part 1: Tumor, kidney, right upper pole; partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
5	T	5

Amendments

Amend Date: [REDACTED] Amended By: [REDACTED]

Original Diagnosis:

1. Tumor, kidney, right upper pole; partial nephrectomy:
Tumor Type:
Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:
Nuclear grade II/IV

Tumor Size:
Greatest diameter is 2.8 cm.

Local Invasion (for renal cortical types):

[page 3 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

[REDACTED]

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CONVENTIONAL MARGIN FREE OF TUMOR. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Referring Physician Contacted

[REDACTED] WAS NOTIFIED VIA E-MAIL ON [REDACTED]

Source: NCI Genomic Data Commons file 1743420a-dd50-4bcf-8547-f6d4ad05cf0d (TCGA-BP-4344.E300F689-2612-4936-9C4F-41C2471B9376.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).